Somatic mutation profile of tumor specimen TCGA-HU-A4GY-01A (aliquot TCGA-HU-A4GY-01A-21D-A24D-08) from TCGA case TCGA-HU-A4GY, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 77.0 years (28,113 days).
Specimen TCGA-HU-A4GY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7c434a7-b91c-4b7d-987c-8fba19aecadb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4GY-10A (Blood Derived Normal), aliquot TCGA-HU-A4GY-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db9c3ad4-f609-4066-a5f8-24bd70afee91

The open-access MAF lists 55 somatic variants for this specimen: 39 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 15, Nonsense Mutation 2, Splice Region 2, Splice Site 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM2 | c.1397T>C p.L466P (on ENST00000341937 / NM_001130084.2; = p.L415P on NM_032432.5) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV56400779; called by muse, mutect2, varscan2
- AK9 | c.2774G>T p.R925I | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV100393385, COSV58138579; called by muse, mutect2
- ATP1A3 | c.2179G>A p.A727T (on ENST00000545399 / NM_001256214.2; = p.A714T on NM_152296.5) | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57485579; called by muse, mutect2
- CACNA2D4 | c.956A>T p.D319V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54945668; called by muse, mutect2, varscan2
- CCDC47 | c.551A>G p.D184G | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56722003; called by muse, mutect2
- CCDC8 | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); catalogued as rs758991386, COSV56772423; called by muse, mutect2
- CGB1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as COSV100031603; called by muse, mutect2
- CKAP4 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as rs899320767, COSV65172173; called by muse, mutect2
- CLCN4 | c.1366A>T p.T456S | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.912); catalogued as COSV66465344; called by muse, mutect2, varscan2
- COL12A1 | c.5336G>A p.R1779H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.883); catalogued as rs748487098, COSV59390679; called by muse, mutect2, varscan2
- COL20A1 | c.1651C>T p.R551C | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.394); catalogued as rs1474251532, COSV58912631; called by muse, mutect2
- CR1L | c.1041G>T p.V347= | Splice Region (SNP) | VAF 15/182 reads (8%) | catalogued as COSV54322984, COSV54330672; called by muse, mutect2
- EIF3B | c.2154G>A p.K718= | Splice Region (SNP) | VAF 5/35 reads (14%) | catalogued as COSV62802840; called by muse, mutect2, varscan2
- ELSPBP1 | c.316T>G p.F106V | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV60413032; called by muse, mutect2
- EPHA7 | c.2790A>T p.E930D | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.023); catalogued as COSV65178074; called by muse, mutect2
- FCAR | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 49/393 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs769096695, COSV62028724; called by muse, mutect2, varscan2
- GDPD3 | c.779G>A p.R260K | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs1192409686, COSV62390812; called by muse, mutect2
- GMEB1 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV53793116; called by muse, mutect2
- GRIK4 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs779846238, COSV70800239; called by mutect2, varscan2
- HMCN1 | c.2464C>T p.P822S | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54881313; called by muse, mutect2
- KIAA1109 | c.6445A>C p.K2149Q | Missense Mutation (SNP) | VAF 5/127 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV52664134; called by muse, mutect2
- LY86 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs745538531, COSV57911030; called by muse, mutect2, varscan2
- NCOA1 | c.3404T>A p.M1135K | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1452878218, COSV56039842; called by muse, mutect2, varscan2
- OR10S1 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs753969769, COSV73342679; called by muse, mutect2, varscan2
- OR2L3 | c.712C>G p.L238V | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV63454600; called by muse, varscan2
- PADI2 | c.1381G>T p.E461* | Nonsense Mutation (SNP) | VAF 9/123 reads (7%) | catalogued as COSV64945385; called by muse, mutect2
- PAG1 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as COSV55055783; called by muse, mutect2, varscan2
- PCDHA11 | c.2174C>T p.T725M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1187011496, COSV56481398; called by mutect2, varscan2
- PDHB | c.1006A>G p.K336E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.022); catalogued as rs767192593, COSV57056443; called by muse, mutect2, varscan2
- POPDC3 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); catalogued as rs111547826, COSV54643244; called by muse, mutect2
- PPIP5K2 | c.1293+1G>T p.X431_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | catalogued as COSV58603125; called by muse, mutect2
- PREX1 | c.3556G>A p.V1186M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.426); catalogued as rs774958876, COSV64248438; called by muse, mutect2
- RASGEF1A | c.1156G>A p.V386I | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs138913845, COSV65667736; called by mutect2, varscan2
- REV3L | c.3163G>T p.A1055S | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as COSV104415782, COSV62625327; called by muse, mutect2, varscan2
- TAX1BP1 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV55290814; called by muse, mutect2
- TECTA | c.4501G>A p.A1501T | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1056976311, COSV50688097; called by muse, mutect2
- TNFRSF8 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs749228869, COSV55794828; called by muse, mutect2, varscan2
- ZNF396 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV60473804; called by muse, mutect2, varscan2
- JRKL | c.1057_1059del p.L353del | In Frame Del (DEL) | VAF 10/74 reads (14%) | called by mutect2, pindel
- ABI1 | c.33G>A p.E11= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV61015341; called by muse, mutect2
- AMIGO2 | c.1362C>T p.S454= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs764019864, COSV56973449; called by mutect2, varscan2
- ASMT | c.729G>A p.P243= (on ENST00000381229; = p.P271= on NM_004043.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/148 reads (10%) | catalogued as rs756221219, COSV67109590; called by muse, mutect2, varscan2
- CACNG7 | c.576C>T p.A192= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs781331621, COSV55813175; called by muse, mutect2
- DACT1 | c.2121G>A p.A707= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV60019673; called by muse, mutect2, varscan2
- IZUMO2 | c.318G>T p.L106= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs752195513, COSV53229302; called by muse, mutect2, varscan2
- LRRC7 | c.3546C>A p.G1182= (on ENST00000651989 / NM_001370785.2; = p.G1149= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as COSV50416573; called by muse, mutect2
- MTHFD1L | c.1617G>A p.R539= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV100944999; called by muse, mutect2
- NR5A2 | c.330T>C p.F110= (on ENST00000367362 / NM_205860.3; = p.F64= on NM_003822.5) | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV52645736, COSV52650184; called by muse, mutect2
- PCDHA5 | c.1446C>T p.D482= | Silent (SNP) | VAF 27/139 reads (19%) | catalogued as rs1328701255, COSV65349916; called by muse, mutect2, varscan2
- SLC25A48 | c.339C>T p.A113= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs552013288, COSV50848094; called by muse, mutect2, varscan2
- TARBP2 | c.993C>T p.T331= (on ENST00000266987 / NM_134323.2; = p.T310= on NM_004178.4) | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV57199100; called by muse, mutect2, varscan2
- TOB1 | c.714G>A p.Q238= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV99278799; called by muse, mutect2, varscan2
- USP51 | c.1632A>G p.P544= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV101540646, COSV72351511; called by muse, mutect2, varscan2
- ZMIZ1 | c.2334C>A p.T778= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as COSV100566471, COSV57890623; called by muse, mutect2
- AL132655.6 | chr20:58840315 G>A | 5'Flank (SNP) | VAF 19/102 reads (19%) | catalogued as COSV58328888; called by muse, mutect2, varscan2
